Gene-level copy-number profile of tumor specimen TCGA-67-3771-01A from TCGA case TCGA-67-3771, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 77.8 years (28,406 days).
Specimen TCGA-67-3771-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.bd8385d5-e8ec-411b-9c9a-10d5682cbbea.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-67-3771-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7394fca4-6ec4-4861-a45a-080a1489e46c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 5,199; copy number 2: 23,600; copy number 3: 18,841; copy number 4: 5,357; copy number 5: 4,793; copy number 6: 1,724; copy number 7: 209; copy number 8: 53; copy number 10: 31.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-67-3771-01A-01D-0944-01): tumor purity 0.46, ploidy 2.88, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:60,719,222–62,611,327, 13 genes: GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3, AL356131.1, MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1, DHFRP5, AL355375.1, AL355375.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,810 genes in 40 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–160,896,076, 788 genes, copy number 5 (broad region; genes not listed).
- chr2:88,811,186–88,861,563, 1 gene, copy number 5 (within-gene range 3–5): AC244205.1.
- chr2:88,857,161–103,276,138, 346 genes, copy number 5 (broad region; genes not listed).
- chr2:143,938,068–220,741,493, 1,193 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr3:84,638,405–86,074,429, 7 genes, copy number 6 (within-gene range 2–6): LINC00971, AC117482.1, LINC02025, AC132660.2, CADM2, MIR5688, CADM2-AS2.
- chr3:86,481,943–88,601,402, 24 genes, copy number 6: LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5.
- chr3:96,753,185–109,410,084, 180 genes, copy number 6 (broad region; genes not listed).
- chr3:111,998,739–117,997,592, 99 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr3:145,523,538–146,606,216, 18 genes, copy number 6: LARP7P4, GM2AP1, RPL21P39, AC055758.2, AC055758.1, AC107021.2, AC107021.1, LNCSRLR, PLOD2, PLSCR4, AC130509.1, AC069528.1, PLSCR2, AC069528.2, PLSCR1, RNU6-428P, PLSCR5, PLSCR5-AS1.
- chr3:147,939,905–151,476,174, 91 genes, copy number 5 (broad region; genes not listed).
- chr3:157,259,742–161,821,908, 70 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr3:164,978,898–165,197,109, 4 genes, copy number 6: SI, Y_RNA, LINC02023, SLITRK3.
- chr3:167,239,843–198,222,513, 613 genes, copy number 6 (broad region; genes not listed).
- chr6:167,607–2,525,976, 38 genes, copy number 5 (within-gene range 2–5): AL035696.2, AL035696.3, AL035696.4, AL035696.1, AL365272.1, DUSP22, IRF4, AL512308.1, EXOC2, AL031770.1, HUS1B, AL357054.1, AL357054.2, AL357054.4, AL357054.5, AL357054.3, AL392183.1, AL356130.1, LINC01622, AL033381.2, AL033381.1, AL033381.3, FOXQ1, LINC01394, AL034346.1, FOXF2, MIR6720, RN7SL352P, AL512329.1, AL512329.2, FOXCUT, FOXC1, GMDS, AL035693.1, GMDS-DT, HMGN2P28, AL031768.2, AL031768.1.
- chr6:52,361,421–52,909,698, 18 genes, copy number 7: PAQR8, EFHC1, TRAM2, TRAM2-AS1, AL109918.2, AL109918.1, TMEM14A, GSTA8P, SREK1IP1P2, GSTA7P, GSTA2, GSTA12P, GSTA1, GSTA6P, GSTA5, GSTA11P, GSTA10P, GSTA3.
- chr7:6,663,974–7,718,607, 29 genes, copy number 5 (within-gene range 4–5): AC073343.2, AC073343.1, ZNF12, PMS2CL, SPDYE20P, RSPH10B2, CCZ1B, OR7E39P, UNC93B2, OR7E136P, OR7E59P, AC079804.2, ALG1L5P, AC079804.1, FAM86LP, AC079804.3, MIR3683, AC092104.1, Y_RNA, C1GALT1, AC005532.2, AC005532.1, AC079448.1, COL28A1, AC004982.1, AC004982.2, MIOS, AC004948.1, RPA3.
- chr8:89,933,331–90,620,077, 4 genes, copy number 6 (within-gene range 3–6): NBN, DECR1, CALB1, AC004083.1.
- chr8:98,024,851–110,105,964, 217 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr8:119,214,625–120,056,201, 19 genes, copy number 6: MAL2-AS1, MIR548AZ, AC021733.4, AC021733.1, CCN3, AC021733.2, AC021733.3, ENPP2, CYCSP23, RN7SKP153, TAF2, AP005717.2, DSCC1, AC021945.1, RN7SL396P, AP005717.1, DEPTOR, RNA5SP277, AC091563.1.
- chr10:4,987,400–5,763,740, 30 genes, copy number 5–10: AKR1C2, AL391427.1, U8, AKR1C3, U8, AKR1C5P, AKR1C8P, AKR1C4, ARL4AP3, AL355303.2, AL355303.1, LINC02561, AKR1C7P, RPL26P28, AL683826.1, UCN3, TUBAL3, NET1, CALML5, CALML3-AS1, CALML3, AL732437.1, AL732437.3, AL732437.2, LASTR, AL365356.2, RN7SL445P, ASB13, TASOR2, AL365356.1.
- chr10:5,776,071–5,776,858, 1 gene, copy number 5: NRBF2P5.
- chr11:33,665,220–38,212,799, 70 genes, copy number 7 (broad region; genes not listed).
- chr11:132,414,977–133,532,519, 1 gene, copy number 5 (within-gene range 4–5): OPCML.
- chr11:132,771,623–135,075,908, 38 genes, copy number 5: AP003784.1, OPCML-IT2, AP004782.1, AP003972.1, OPCML-IT1, AP004606.1, LINC02743, SPATA19, AP001979.1, IGSF9B, MIR4697, LINC02730, LINC02731, AP000911.1, JAM3, PTP4A2P2, NCAPD3, AP001775.1, AP001775.2, VPS26B, THYN1, ACAD8, GLB1L3, AP000859.1, GLB1L2, B3GAT1, B3GAT1-DT, AP004550.1, AP001999.3, AP001999.1, AP001999.2, LINC02706, LINC02714, AP003062.2, LINC02697, AP003062.1, LINC02717, LINC02684.
- chr12:52,751,978–53,064,379, 17 genes, copy number 5: KRT127P, ARL2BPP2, KRT76, AC107016.2, KRT3, KRT4, KRT79, AC107016.1, KRT78, RPL7P41, KRT8, KRT18, EIF4B, AC068888.2, AC068888.1, TNS2, MIR6757.
- chr13:70,459,464–114,337,626, 552 genes, copy number 5–6 (broad region; genes not listed).
- chr14:32,200,433–37,172,606, 93 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr14:48,819,360–64,601,644, 336 genes, copy number 5 (broad region; genes not listed).
- chr14:67,819,779–68,730,218, 1 gene, copy number 5 (within-gene range 4–5): RAD51B.
- chr14:68,236,243–91,575,271, 431 genes, copy number 5–10 (broad region; genes not listed).
- chr14:91,603,173–91,605,319, 2 genes, copy number 6: POLR3GP1, NANOGP7.
- chr20:5,928,085–33,243,311, 477 genes, copy number 5 (broad region; genes not listed).
- chr20:39,932,922–64,313,132, 599 genes, copy number 5 (broad region; genes not listed).
- chr21:10,328,411–24,547,942, 184 genes, copy number 5–8 (broad region; genes not listed).
- chr21:25,639,258–25,717,562, 1 gene, copy number 6 (within-gene range 3–6): JAM2.
- chr21:25,646,113–26,573,286, 17 genes, copy number 6 (within-gene range 2–6): AP000224.1, FDX1P2, ATP5PF, GABPA, LLPHP2, APP, AP001442.1, RNU6-123P, AP001439.1, AP000229.1, RNU6-926P, AP001595.2, AP001595.1, AP001596.1, CYYR1-AS1, AP001596.2, CYYR1.
- chr22:26,858,634–27,460,060, 19 genes, copy number 5: LINC01422, Z97353.1, Z97353.2, AL008638.3, RNU6-1066P, AL008638.5, AL008638.4, AL008638.2, AL008638.6, AL008638.1, AL021153.1, LINC01638, AL020994.3, AL020994.1, LINC02554, AL020994.2, AL049536.1, AL050402.2, AL050402.1.
- chr22:30,652,051–30,667,887, 1 gene, copy number 5 (within-gene range 4–5): DUSP18.
- chr22:30,664,961–31,662,432, 45 genes, copy number 5: AC003072.2, OSBP2, MIR3200, EIF4HP2, MORC2-AS1, MORC2, TUG1, AC004542.5, AC004542.4, AC004542.6, AC004542.3, AC004542.2, AC004542.1, AC005005.4, RN7SL633P, SMTN, AC005005.3, SELENOM, AC005005.2, INPP5J, PLA2G3, AC005005.1, MIR3928, RNF185, RNF185-AS1, LIMK2, RNU6-1128P, Y_RNA, PIK3IP1, PIK3IP1-DT, RNA5SP496, PATZ1, LINC01521, RNU6-338P, DRG1, EIF4ENIF1, AL096701.3, RNU6-28P, SFI1, AL096701.4, H2AZP6, AL096701.2, AL096701.1, PISD, MIR7109.
- chr22:36,847,372–39,532,761, 136 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,815. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
